CCDI case PBCMYH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/e4f5e26c-c2c0-40c5-b4ca-818608ee0a24

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.8 years (1,021 days).

Biospecimens (3 samples)
- Sample 0DVNXB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVNXF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVNYN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
